Somatic mutation profile of tumor specimen TCGA-ZF-A9R1-01A (aliquot TCGA-ZF-A9R1-01A-11D-A391-08) from TCGA case TCGA-ZF-A9R1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.1 years (29,610 days).
Specimen TCGA-ZF-A9R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e1a154d-3904-46c0-a3e7-85465cb974dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R1-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R1-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58a73477-bdfa-4031-a7b2-7acee1e66ba1

The open-access MAF lists 108 somatic variants for this specimen: 79 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 24, Nonsense Mutation 4, Frame Shift Ins 3, RNA 3, Frame Shift Del 3, Splice Region 1, In Frame Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUX2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565909334, CM129347, COSV55641526; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 40/143 reads (28%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- ACAT1 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54921781; called by muse, mutect2, varscan2
- ADAMTS12 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1403815771, COSV61271785; called by muse, mutect2, varscan2
- AFF3 | c.1038A>C p.P346= | Splice Region (SNP) | VAF 28/96 reads (29%) | catalogued as COSV57864483; called by muse, mutect2, varscan2
- APOBEC4 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1196091183, COSV58018191; called by muse, mutect2
- ARHGEF2 | c.2688T>A p.S896R (on ENST00000361247 / NM_001162383.2; = p.S868R on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); catalogued as COSV58114250; called by muse, mutect2, varscan2
- ARMC8 | c.244G>A p.E82K (on ENST00000469044 / NM_001363941.2; = p.E68K on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV61769098; called by muse, mutect2, varscan2
- CALCRL | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1450688404, COSV66473507, COSV66476306; called by muse, mutect2, varscan2
- CCAR1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56272063; called by muse, mutect2, varscan2
- CD19 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs556457823, COSV61189265; called by muse, mutect2, varscan2
- CDKN1A | c.189del p.F63Lfs*85 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV55190473; called by mutect2, pindel, varscan2
- CSMD3 | c.3427C>T p.P1143S (on ENST00000297405 / NM_001363185.1; = p.P1039S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52093613; called by muse, mutect2, varscan2
- CYP2D6 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV62244927; called by muse, varscan2
- DMBT1 | c.6370C>G p.P2124A (on ENST00000338354 / NM_001377530.1; = p.P1367A on NM_004406.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV57544883; called by muse, mutect2, varscan2
- ELOA2 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs536656582, COSV55302935; called by muse, mutect2, varscan2
- FAM47C | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs782414838, COSV100792281, COSV63727724; called by muse, mutect2, varscan2
- FAT3 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs773058850, COSV53149152, COSV53186335; called by muse, mutect2, varscan2
- FER1L6 | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67551769, COSV67552977; called by muse, mutect2, varscan2
- FMN2 | c.2908C>A p.L970I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.305); catalogued as COSV60434260; called by muse, varscan2
- GJA5 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV54785722; called by muse, mutect2, varscan2
- GPATCH1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50121134; called by muse, mutect2, varscan2
- GRIN2D | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 76/232 reads (33%) | catalogued as rs1331914551, COSV99616720; called by muse, mutect2, varscan2
- HIPK4 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV52524045; called by muse, mutect2
- IPO13 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54838059; called by muse, mutect2, varscan2
- KCNA3 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63902276; called by muse, mutect2, varscan2
- KCNT2 | c.1277T>A p.F426Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54096401; called by muse, varscan2
- KIAA2026 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV67356679; called by muse, mutect2, varscan2
- LMAN1L | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1217449369, COSV59002873; called by muse, mutect2, varscan2
- LRRK2 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54157855, COSV54162951; called by muse, mutect2, varscan2
- LRRN3 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs774528058, COSV57822371; called by muse, mutect2, varscan2
- MAP9 | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV60905687; called by muse, varscan2
- MAP9 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60905691; called by muse, varscan2
- MAPRE2 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55820480; called by muse, mutect2, varscan2
- MTTP | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV55508372; called by muse, mutect2, varscan2
- NAA15 | c.219G>C p.L73F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721468; called by muse, mutect2, varscan2
- NCKAP1L | c.2515G>T p.A839S | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV53210059; called by muse, mutect2, varscan2
- NOS1 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs999942391, COSV57613504, COSV57617746; called by muse, mutect2, varscan2
- NPM3 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV63382594; called by muse, mutect2, varscan2
- OPCML | c.471T>G p.C157W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59438438; called by muse, mutect2, varscan2
- OR4D2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73459824; called by muse, varscan2
- OR4K5 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs201394876; called by muse, mutect2, varscan2
- PDCD1 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs756100729, COSV57690800; called by muse, mutect2, varscan2
- PF4V1 | c.172A>T p.I58F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV99896364; called by muse, varscan2
- PKHD1 | c.8237A>T p.E2746V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV61888054; called by muse, mutect2, varscan2
- PKHD1 | c.8236G>A p.E2746K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs769588376, COSV61883219; called by muse, mutect2, varscan2
- PTPRS | c.4684G>A p.E1562K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778163463, COSV53639611; called by muse, varscan2
- QRICH2 | c.3611C>A p.P1204H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1340145184, COSV99429458; called by muse, mutect2, varscan2
- RALYL | c.736T>G p.C246G | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV104439845, COSV72823650; called by muse, mutect2, varscan2
- RHCE | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53802271; called by muse, mutect2, varscan2
- RORA | c.458G>C p.R153T (on ENST00000335670 / NM_134261.3; = p.R178T on NM_002943.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55042263; called by muse, mutect2, varscan2
- RPAP1 | c.3532C>G p.L1178V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as COSV58539052, COSV58541213; called by muse, mutect2, varscan2
- RYR2 | c.12769C>T p.R4257* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs376974288; called by muse, mutect2, varscan2
- SFMBT2 | c.2068A>T p.R690W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62813832; called by muse, mutect2, varscan2
- SLC26A7 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52599914; called by muse, mutect2, varscan2
- SLC2A11 | c.1423A>G p.N475D (on ENST00000345044 / NM_001024938.4; = p.N482D on NM_030807.5) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV55393075; called by muse, mutect2, varscan2
- SOS1 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67676705; called by muse, mutect2, varscan2
- SPARCL1 | c.1302G>C p.M434I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV56805376; called by muse, mutect2, varscan2
- TAS1R2 | c.2081T>G p.V694G | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV64746194; called by muse, mutect2, varscan2
- TEDDM1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs1165964545, COSV62380608; called by muse, mutect2
- TENM3 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.551); catalogued as rs1179197424, COSV101305116; called by muse, mutect2
- THSD7B | c.1690del p.R564Vfs*3 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as COSV55692365, COSV55716754; called by mutect2, pindel, varscan2
- TICAM1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV50238971, COSV99941174; called by muse, mutect2, varscan2
- TMTC3 | c.1554dup p.Y519Ifs*8 | Frame Shift Ins (INS) | VAF 20/101 reads (20%) | catalogued as rs746894544; called by mutect2, pindel, varscan2
- TRPC6 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.157); catalogued as rs1182279573, COSV100723694; called by muse, mutect2, varscan2
- UQCRC2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51673316; called by muse, mutect2, varscan2
- VPS16 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV66797220; called by muse, mutect2, varscan2
- WDR17 | c.2616C>G p.I872M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV54579414; called by muse, mutect2, varscan2
- WNT9B | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs959619683, COSV51518827; called by muse, mutect2, varscan2
- ZIC3 | c.765G>C p.W255C | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54975701; called by muse, mutect2, varscan2
- ZMYM2 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.971); catalogued as COSV67032816, COSV67035858; called by muse, mutect2, varscan2
- ZMYM3 | c.2619C>G p.I873M | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV58739610; called by muse, mutect2, varscan2
- ZNF175 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV51797258; called by muse, mutect2, varscan2
- ZNF521 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs751157753, COSV64124837; called by muse, varscan2
- ZNF676 | c.1229C>T p.S410L (on ENST00000650058; = p.S378L on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV68092820; called by muse, mutect2
- CYP4B1 | c.195dup p.S66Efs*31 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); called by mutect2, varscan2
- KDM6A | c.1562_1578delinsA p.T521Nfs*22 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by pindel, varscan2*
- NIPAL1 | c.655_666del p.I219_V222del | In Frame Del (DEL) | VAF 28/151 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.2316G>A p.R772= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as COSV56976449; called by muse, mutect2, varscan2
- CCDC113 | c.285G>C p.L95= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV54687000; called by muse, mutect2, varscan2
- CDK18 | c.825C>T p.F275= (on ENST00000506784 / NM_212503.3; = p.F245= on NM_002596.4) | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV63728410; called by muse, mutect2, varscan2
- CHD4 | c.4278T>C p.F1426= (on ENST00000357008 / NM_001363606.2; = p.F1439= on NM_001273.5) | Silent (SNP) | VAF 67/252 reads (27%) | catalogued as COSV58907221; called by muse, mutect2, varscan2
- EXO1 | c.1803T>A p.T601= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV62218823; called by muse, mutect2, varscan2
- EXOSC9 | c.189T>G p.L63= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV54667208; called by muse, mutect2, varscan2
- GALR2 | c.102C>T p.L34= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100203638; called by muse, mutect2
- GREB1 | c.3777C>T p.V1259= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV52192473; called by muse, mutect2, varscan2
- GRM7 | c.1413G>C p.G471= | Silent (SNP) | VAF 9/166 reads (5%) | catalogued as COSV63157767; called by muse, mutect2
- IRF3 | c.1116C>G p.L372= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV59191036, COSV59192188; called by muse, mutect2, varscan2
- ITGAD | c.9C>T p.F3= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as rs773502631, COSV66758158; called by muse, mutect2, varscan2
- KAT2B | c.1491C>T p.H497= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1353045773, COSV55432484; called by muse, mutect2, varscan2
- MBD4 | c.1113G>A p.L371= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV51445307; called by muse, mutect2, varscan2
- MPZL1 | c.435C>T p.V145= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV63257015; called by muse, mutect2, varscan2
- NMRK2 | c.204C>T p.T68= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs142817100; called by muse, mutect2, varscan2
- NOS1 | c.1254G>A p.S418= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs946356254, COSV57608982; called by muse, mutect2, varscan2
- OR4D2 | c.342C>T p.F114= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as rs1407997486, COSV73459825; called by muse, varscan2
- OR4D2 | c.771C>G p.L257= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs983722456, COSV73459826; called by muse, mutect2, varscan2
- OVCH1 | c.1749C>A p.P583= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs929481308, COSV58966114; called by muse, mutect2, varscan2
- SALL3 | c.2250C>T p.N750= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs932625576, COSV73306189; called by muse, mutect2, varscan2
- SLC28A1 | c.774C>G p.V258= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV54482882; called by muse, mutect2, varscan2
- SLIT1 | c.2817C>G p.T939= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV56594848; called by muse, mutect2, varscan2
- WNT9B | c.517C>T p.L173= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51519411; called by muse, mutect2, varscan2
- WWC2 | c.3366G>A p.L1122= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV67857587, COSV67860574; called by muse, mutect2, varscan2
- CEP295 | chr11:93733545 G>A | 3'Flank (SNP) | VAF 30/125 reads (24%) | catalogued as rs750388419; called by muse, mutect2, varscan2
- DCHS2 | n.357G>T | RNA (SNP) | VAF 16/76 reads (21%) | catalogued as COSV59734422; called by muse, mutect2, varscan2
- FRMPD2B | n.598G>A | RNA (SNP) | VAF 87/585 reads (15%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31301G>C | Intron (SNP) | VAF 24/99 reads (24%) | catalogued as COSV55169428; called by muse, mutect2, varscan2
- OR2W5 | n.349C>T | RNA (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
